Somatic mutation profile of tumor specimen 0DX8KJ from CCDI case PBCPXK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.3 years (4,843 days).
Specimen 0DX8KJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b899ea8f-4a7d-436e-9b1b-89a9ea0e9ca3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX8JQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/225e8f22-e457-4ca7-adc2-963d3564d0d5

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD33 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.795); catalogued as rs369307221; called by muse, varscan2
- KDM6A | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 358/390 reads (92%) | catalogued as COSV100938725; called by muse, varscan2
- LAMA2 | c.5060G>C p.R1687P | Missense Mutation (SNP) | VAF 142/334 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.153); catalogued as COSV70349051; called by muse, varscan2
- MSRB2 | c.219G>A p.P73= | Splice Region (SNP) | VAF 238/531 reads (45%) | catalogued as rs199668231, COSV100919720; called by muse, varscan2
- ACTL8 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 230/489 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, varscan2
- GAL3ST2 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- OR2Y1 | c.321G>T p.L107= | Silent (SNP) | VAF 50/179 reads (28%) | called by muse, varscan2
